Somatic mutation profile of tumor specimen MBCproject_0095_T1_WES (aliquot MBCproject_0095_T1_WES_1) from CMI case MBCproject_0095, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 32.1 years (11,708 days).
Specimen MBCproject_0095_T1_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Liver; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f086d49-97a3-4c7a-a463-ba0738146083.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCproject_0095_SALIVA (Saliva), aliquot MBCproject_0095_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbeeca5f-49a0-4a33-bf5c-90614653c38b

The open-access MAF lists 62 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 17, Frame Shift Del 4, Splice Site 3, Intron 2, RNA 2, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1, 3'Flank 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A2 | c.337T>C p.Y113H | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs1235251595; called by muse, mutect2
- C12orf56 | c.1459A>G p.T487A (on ENST00000543942 / NM_001170633.2; = p.T327A on NM_001099676.3) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs1385655558; called by muse, mutect2, varscan2
- CREB3L3 | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50249569; called by muse, mutect2
- ERVMER34-1 | c.557G>A p.W186* | Nonsense Mutation (SNP) | VAF 25/103 reads (24%) | catalogued as COSV66920659; called by muse, mutect2, varscan2
- IRAK1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs1346294230; called by muse, mutect2
- KDM6B | c.3532C>T p.R1178W | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs779500605; called by muse, mutect2, varscan2
- NOS1 | c.4036G>C p.E1346Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV57606555; called by muse, mutect2, varscan2
- PLEKHA7 | c.2094C>G p.F698L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63044368; called by muse, mutect2, varscan2
- PLXNA4 | c.2626del p.V876Sfs*29 | Frame Shift Del (DEL) | VAF 38/250 reads (15%) | catalogued as COSV58170160; called by mutect2, pindel, varscan2
- POTEE | c.2479T>C p.F827L | Missense Mutation (SNP) | VAF 26/531 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs1192825275; called by muse, mutect2
- TEKT3 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 20/363 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1241081916, COSV58628129; called by muse, mutect2
- TP53 | c.293del p.P98Lfs*25 | Frame Shift Del (DEL) | VAF 11/88 reads (13%) | catalogued as COSV52850165; called by mutect2, pindel, varscan2
- TULP3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs151311529; called by mutect2, varscan2
- UBA52 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV55889757; called by muse, mutect2
- ARSL | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C4BPA | c.663T>G p.N221K | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GDF1 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2
- HMCN1 | c.4200+2T>A p.X1400_splice | Splice Site (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- KDR | c.379_414del p.A127_I138del | In Frame Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel
- KRT15 | c.581+8C>T | Splice Region (SNP) | VAF 24/327 reads (7%) | called by muse, mutect2
- LCT | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2
- LRP1B | c.10661C>A p.S3554Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- MINK1 | c.3424G>A p.A1142T | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MPO | c.29G>C p.R10T | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.227); called by muse, mutect2
- OPTN | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2
- PCDHGB5 | c.1452_1483del p.Y485Gfs*22 | Frame Shift Del (DEL) | VAF 16/174 reads (9%) | called by mutect2, pindel
- PDGFD | c.547T>C p.W183R | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC9A1 | c.1299_1318del p.W434Yfs*38 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- SMARCAL1 | c.2154G>T p.L718F | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- SNIP1 | c.576G>C p.R192S | Missense Mutation (SNP) | VAF 17/241 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- SRP54 | c.837A>G p.I279M | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.217); called by muse, mutect2
- TLN1 | c.5614-15_5641del p.X1872_splice | Splice Site (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel
- TMBIM1 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TTC13 | c.137C>G p.T46S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, varscan2
- VPS13D | c.5428A>C p.I1810L | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2
- VWF | c.7771-1G>A p.X2591_splice | Splice Site (SNP) | VAF 34/520 reads (7%) | called by muse, mutect2
- ZFHX4 | c.5725G>C p.A1909P | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2
- ZNF556 | c.806G>C p.R269T | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2
- B3GALNT1 | c.468C>G p.T156= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- CLIP2 | c.261G>C p.V87= | Silent (SNP) | VAF 28/327 reads (9%) | called by muse, mutect2
- GRAMD1B | c.51G>A p.T17= | Silent (SNP) | VAF 22/192 reads (11%) | catalogued as COSV59201939; called by mutect2, varscan2
- KIF26B | c.1743C>T p.N581= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs748806574; called by muse, mutect2, varscan2
- KRTAP26-1 | c.96C>A p.T32= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs1421857524; called by muse, mutect2
- LYST | c.3720C>T p.D1240= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- MEN1 | c.1425G>A p.P475= | Silent (SNP) | VAF 55/525 reads (10%) | catalogued as rs1060503795, COSV53641026; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC4 | c.10026C>A p.T3342= | Silent (SNP) | VAF 28/464 reads (6%) | catalogued as rs879089592; called by muse, mutect2
- MYBPC3 | c.3661C>T p.L1221= | Silent (SNP) | VAF 15/266 reads (6%) | called by muse, mutect2
- OR1K1 | c.669A>T p.A223= | Silent (SNP) | VAF 14/116 reads (12%) | called by muse, mutect2, varscan2
- PCDHB7 | c.1509G>T p.L503= | Silent (SNP) | VAF 44/357 reads (12%) | called by muse, varscan2
- PPP4R3B | c.93C>T p.Y31= | Silent (SNP) | VAF 15/146 reads (10%) | called by muse, mutect2, varscan2
- PROX1 | c.120G>C p.T40= | Silent (SNP) | VAF 17/223 reads (8%) | catalogued as COSV54779863; called by muse, mutect2
- PSG7 | c.594C>G p.T198= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- PTX3 | c.717T>C p.Y239= | Silent (SNP) | VAF 16/265 reads (6%) | called by muse, mutect2
- TMEM64 | c.378C>G p.V126= | Silent (SNP) | VAF 24/164 reads (15%) | called by muse, mutect2, varscan2
- VWF | c.7056C>G p.G2352= | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as CS114290; called by muse, mutect2
- AZIN1 | chr8:102864451 C>T | 5'Flank (SNP) | VAF 7/33 reads (21%) | catalogued as rs894194981; called by muse, mutect2, varscan2
- BTNL8 | c.787+28G>C | Intron (SNP) | VAF 16/193 reads (8%) | called by muse, mutect2
- C4BPB | c.410-1237C>G | Intron (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- FAM169B | n.684A>T | RNA (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- PRKCG | c.*49G>C | 3'UTR (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1592C>G | RNA (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- U8 | chr15:30113922 A>G | 3'Flank (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
